Gene-level copy-number profile of tumor specimen C3L-06096-02 from CPTAC case C3L-06096, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.7 years (23,277 days).
Specimen C3L-06096-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 25713edb-71a0-4412-987d-239ba5f64d1b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06096-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/0ed6afb2-a9ed-4ac3-835a-3b80c83eff1f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 427; copy number 2: 18,250; copy number 3: 18,677; copy number 4: 17,284; copy number 5: 835; copy number 6: 1,006; copy number 8: 1,451; copy number 10: 448.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,899 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:62,275,361–159,233,377, 1,899 genes, copy number 8–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 427. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
